Somatic mutation profile of tumor specimen MP2PRT-PAWAUK-TMP1-A (aliquot MP2PRT-PAWAUK-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWAUK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,905 days).
Specimen MP2PRT-PAWAUK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d81cec37-07df-4be7-9611-418943269f25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAUK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAUK-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b079a557-13d3-4cb4-8f3f-10c4457b42f6

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6317G>A p.R2106H | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520213, CM159385, COSV64678237; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 33/225 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 81/354 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRWD1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 227/538 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs147327994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRAP | c.2846C>T p.A949V (on ENST00000359988 / NM_001322945.2; = p.A914V on NM_006175.4) | Missense Mutation (SNP) | VAF 93/440 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs763519063, COSV63488222; called by muse, mutect2, varscan2
- ODF3L2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs527511512; called by muse, mutect2, varscan2
- PDS5B | c.2170dup p.R724Pfs*16 | Frame Shift Ins (INS) | VAF 28/195 reads (14%) | catalogued as rs746601412; called by mutect2, varscan2
- PMEL | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 106/258 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201624440; called by muse, mutect2, varscan2
- PWWP3B | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 97/606 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs373158939, COSV61799340; called by muse, mutect2, varscan2
- SAGE1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 32/483 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV61012464; called by muse, mutect2
- VRTN | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 78/904 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs199857443; called by muse, mutect2
- BCORL1 | c.521T>C p.F174S | Missense Mutation (SNP) | VAF 336/1045 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- C8A | c.173A>C p.Y58S | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CREBBP | c.4983G>T p.M1661I | Missense Mutation (SNP) | VAF 27/744 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- DIO2 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 205/610 reads (34%) | called by muse, mutect2, varscan2
- DSP | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 63/346 reads (18%) | called by muse, mutect2, varscan2
- FAM205A | c.1297T>C p.F433L | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FSCB | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 101/606 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LY6K | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 117/459 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- TMPRSS9 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TNRC6A | c.1982G>T p.S661I | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2
- ANK1 | c.2070C>T p.H690= | Silent (SNP) | VAF 92/344 reads (27%) | catalogued as rs766385545; called by muse, mutect2, varscan2
- C8orf34 | c.21G>A p.S7= | Silent (SNP) | VAF 50/518 reads (10%) | catalogued as rs1444358877; called by muse, mutect2
- CACNA1F | c.3432C>T p.G1144= | Silent (SNP) | VAF 99/520 reads (19%) | catalogued as COSV59903363; called by muse, mutect2, varscan2
- GJB6 | c.138C>T p.D46= | Silent (SNP) | VAF 125/398 reads (31%) | catalogued as rs748793847; called by muse, mutect2, varscan2
- MLLT10 | c.240+17998_240+18000delinsACCAGTCG | Intron (INS) | VAF 48/388 reads (12%) | called by pindel, varscan2*
